Somatic mutation profile of tumor specimen C3L-01426-54 (aliquot CPT0284650002) from CPTAC case C3L-01426, project CPTAC-3 (Hematopoietic and reticuloendothelial systems — Myeloid Leukemias). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 18.3 years (6,694 days).
Specimen C3L-01426-54: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 62ee3d10-a7d9-4568-8653-0ffb8473e73c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-01426-52 (Buccal Cell Normal), aliquot CPT0284710001; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/273e05fe-59a9-482c-a312-736832caf334

The open-access MAF lists 6 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2, 5'UTR 1, Nonsense Mutation 1, In Frame Ins 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FLT3 | c.1775T>C p.V592A | Missense Mutation (SNP) | VAF 16/147 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.04); catalogued as rs1057520025, COSV54051432, COSV54058572, COSV54074139; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- BCL11B | c.2294C>T p.S765L (on ENST00000357195 / NM_001282237.2; = p.S694L on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/526 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1220663516, COSV61733464; called by muse, mutect2
- CBFB | c.259_260insGGGACTCCT p.D87delinsGDSY | In Frame Ins (INS) | VAF 22/200 reads (11%) | catalogued as COSV52001569; called by mutect2, pindel
- KDM3B | c.2815_2816insAGGAC p.F939* | Nonsense Mutation (INS) | VAF 28/206 reads (14%) | called by mutect2, pindel
- FLNA | c.5773C>T p.L1925= (on ENST00000369850 / NM_001110556.2; = p.L1917= on NM_001456.3) | Silent (SNP) | VAF 32/134 reads (24%) | called by muse, mutect2, varscan2
- CHIA | c.-28C>T | 5'UTR (SNP) | VAF 16/130 reads (12%) | called by mutect2, varscan2
